Somatic mutation profile of tumor specimen TCGA-D1-A17N-01A (aliquot TCGA-D1-A17N-01A-11D-A12J-09) from TCGA case TCGA-D1-A17N, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 46.7 years (17,045 days).
Specimen TCGA-D1-A17N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97a7f5fd-57ee-4da6-8600-b9e7bd5b1df6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A17N-10A (Blood Derived Normal), aliquot TCGA-D1-A17N-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4dc53a0-53af-4910-8125-b218190e7197

The open-access MAF lists 32 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 20, Silent 6, Nonsense Mutation 4, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 29/130 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.79T>G p.Y27D | Missense Mutation (SNP) | VAF 73/313 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as CM147224, COSV64290549, COSV64290556, COSV64292877; called by muse, mutect2, varscan2
- PTEN | c.402G>C p.M134I | Missense Mutation (SNP) | VAF 86/307 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1114167676, CM1211213, COSV64291845, COSV64293372, COSV64295066; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABL1 | c.2690C>A p.P897H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs747618171, COSV59328167; called by muse, mutect2, varscan2
- AHNAK2 | c.7602G>T p.Q2534H | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); catalogued as COSV60911540; called by muse, mutect2, varscan2
- ASTL | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.055); catalogued as COSV60903835; called by muse, mutect2, varscan2
- BRDT | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs376776587; called by muse, mutect2, varscan2
- C18orf21 | c.434C>G p.A145G | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV52449264; called by muse, mutect2, varscan2
- COPG1 | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs756754245, COSV59113192; called by muse, mutect2, varscan2
- DNAJC24 | c.269T>C p.V90A | Missense Mutation (SNP) | VAF 18/502 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV67917267; called by muse, mutect2
- GNL2 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1279447904, COSV66079923; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2011G>T p.E671* (on ENST00000265755 / NM_016328.3; = p.X656_splice on NM_005685.4) | Nonsense Mutation (SNP) | VAF 76/291 reads (26%) | catalogued as COSV56085273, COSV56085548, COSV56086323; called by muse, mutect2, varscan2
- IL20 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 111/407 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV65584407; called by muse, mutect2, varscan2
- KCMF1 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.106); catalogued as rs770915691, COSV69053389; called by muse, mutect2, varscan2
- KIF1A | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV57485762; called by muse, mutect2, varscan2
- P4HA2 | c.493A>C p.S165R | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs1255717088, COSV51324259; called by muse, mutect2, varscan2
- PADI6 | c.1798C>T p.P600S | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as COSV61884106; called by muse, mutect2, varscan2
- PRKCH | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 38/146 reads (26%) | catalogued as rs772141815, COSV60647007; called by muse, mutect2, varscan2
- RTN2 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 35/149 reads (23%) | catalogued as COSV55593302; called by muse, mutect2, varscan2
- SPATA22 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 73/304 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs530912497, COSV52152024; called by muse, mutect2, varscan2
- SPTBN4 | c.2809G>A p.V937I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as rs754511407, COSV58946069; called by muse, mutect2, varscan2
- TCERG1 | c.1984C>T p.R662* | Nonsense Mutation (SNP) | VAF 49/164 reads (30%) | catalogued as COSV57035797; called by muse, mutect2, varscan2
- TNFRSF11B | c.1004A>T p.K335I | Missense Mutation (SNP) | VAF 138/507 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV52070072; called by muse, mutect2, varscan2
- TPO | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 52/343 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs752827072, COSV61098226; called by muse, mutect2, varscan2
- PIK3R1 | c.1369_1374del p.Q457_E458del (on ENST00000521381 / NM_181523.3; = p.Q187_E188del on NM_181504.4) | In Frame Del (DEL) | VAF 32/167 reads (19%) | called by mutect2, pindel, varscan2
- PTEN | c.121del p.R41Dfs*13 | Frame Shift Del (DEL) | VAF 117/473 reads (25%) | called by mutect2, pindel, varscan2
- ANKAR | c.3771C>A p.I1257= | Silent (SNP) | VAF 50/169 reads (30%) | catalogued as rs1316923652, COSV55611026; called by muse, mutect2, varscan2
- CCDC60 | c.1536C>T p.I512= | Silent (SNP) | VAF 37/160 reads (23%) | catalogued as rs372553410; called by muse, mutect2, varscan2
- IQCA1 | c.420A>G p.Q140= | Silent (SNP) | VAF 109/377 reads (29%) | catalogued as rs558106245, COSV54499003; called by muse, mutect2, varscan2
- KCMF1 | c.669C>A p.S223= | Silent (SNP) | VAF 39/147 reads (27%) | catalogued as COSV69053428, COSV69053733; called by muse, mutect2, varscan2
- REV3L | c.6463T>C p.L2155= | Silent (SNP) | VAF 34/157 reads (22%) | catalogued as rs751323719, COSV62617256; called by muse, mutect2, varscan2
- ZNF425 | c.1365C>T p.N455= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs747431173, COSV65200952; called by mutect2, varscan2
